Surgical pathology report (de-identified scan), TCGA case TCGA-B6-A0IC, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Duke, specimen TCGA-B6-A0IC-01A (Primary Tumor).

ICB-0-3

Adenocarcinoma, papillary and infiltrating 8503/3

Site Code breast, NOS C50.9 1/10/11 hr

Patient:

Surgical Pathology

Surg Path

CLINICAL HISTORY:

year old white female with right subareolar breast mass times 3 month.
Right breast carcinoma.

GROSS EXAMINATION:

A. "Right breast mass-wide local excision" in formalin. The specimen consists of a portion of breast tissue with a skin ellipse and nipple. The skin ellipse measures 9 x 3.5 cm. The underlying breast tissue measures 10 x 4 x 4 cm. The outer surface was inked in blue. Directly beneath the skin ellipse is a 2.5 x 2 x 1.5 cm mass composed of tan firm friable tissue with focal areas of hemorrhage. The mass is sharply circumscribed. The mass is 0.8 cm from the deep surgical margin.

Block Summary:

A1: Section of nipple.

A2-A11: Section of mass including deep surgical margin.

MICROSCOPIC EXAMINATION:

Large portions of the tumor are made up of well-formed papillary tumor with fibrovascular cores lined by malignant, stratified, complicated, epithelium. In addition, cribriform and tubular foci infiltrate desmoplastic fibrous tissue.

This case was reviewed by Dr.

DIAGNOSIS:

A. "RIGHT BREAST MASS- WIDE LOCAL EXCISION":

INVASIVE PAPILLARY ADENOCARCINOMA OF BREAST (2.5 CM IN GREATEST DIAMETER).
MARGINS OF RESECTION ARE FREE OF TUMOR

Verified by:

i.d. i.d.

Date

• Result for:

Source: NCI Genomic Data Commons file 6509a179-0b55-464b-8425-aed101b1d4e1 (TCGA-B6-A0IC.8AABC46F-03C7-4FBF-AC20-2C862E303A8B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).